CCDI case PBCRFR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/cfac0e09-4db9-471b-93b9-0018d26d56e0

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Liver; Age at diagnosis: 17.9 years (6,530 days).

Biospecimens (3 samples)
- Sample 0DXFCR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXFD4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXFDH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
